Surgical pathology report (de-identified scan), TCGA case TCGA-AX-A3FS, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Gynecologic Oncology Group, specimen TCGA-AX-A3FS-01A (Primary Tumor).

[page 1 of 3]
Redac

[page 2 of 3]
Accession Number	Collected Date/Time	Received Date/Time	Pathologist
------------------	------------------------	-----------------------	-------------

Endometrioid adenocarcinoma, not otherwise characterized

HISTOLOGIC GRADE:

FIGO grade 3

MYOMETRIAL INVASION:

Present

Depth of invasion: 5 mm

Myometrial thickness: 25 mm

INVOLVEMENT OF CERVIX:

Not involved

*PERITONEAL ASCITIC FLUID:

*Negative for malignancy/normal/benign

*MARGINS:

*Uninvolved by invasive carcinoma

LYMPH-VASCULAR INVASION:

Present

PATHOLOGIC STAGING (pTNM [FIGO]):

pT1a[IA]: Tumor limited to endometrium or invades less than one-half of the myometrium

pN0: No regional lymph node metastasis

Pelvic lymph nodes:

Number examined: 16

Number involved: 0

Distant metastasis - Not applicable

Specimen(s):

1. UTERUS, TUBES AND OVARIES

2. RIGHT PELVIC NODE

3. LEFT PELVIC NODE

Clinical Information:

Endometrial cancer.

Frozen Section Diagnosis:

1FSA: High grade endometrioid adenocarcinoma

Gross Description:

1) Specimen 1 designated as "uterus, tubes and ovaries" is received in fresh in a container labeled with the patient's name and medical record number and consists of a hysterectomy specimen which weighs 260 grams. The uterus measures 14 x 9 x 5 cm. The cervix measures 6.5 x 4.5 x 4. The right ovary measures 2 x 1.5 x 1.5 cm. The right tube measures 4 cm in length. The left ovary measures 2 x 2 x 1.5 and the left tube

Patient Name:

Accession No.:

- Surg Path Final Report			
Accession Number	Collected Date/Time	Received Date/Time	Pathologist

measures 4.6 cm in length. The specimen is opened to reveal an endometrial mass. The endometrial mass is anterior and posterior and measures 4 x 3.5 x 1.2 cm. It is friable and appears to show some invasion. The mass does not extend into the endocervical canal, distally. Section is taken for frozen and submitted in cassette 1FSA. A portion of the tumor is submitted in RPMI for Precision Therapeutics as requested. A small amount of the tumor is submitted for the study

for

The specimen is as follows:

[page 3 of 3]
Patient: _____,

Page 3 of 3

1FSA: Frozen section
1B: Anterior cervix
1C: Posterior cervix
1D: Probable fibroid
1E: Subserosal fibroids
1F: Anterior portion of the tumor
1G & H: Anterior portion of tumor
1I & J: Posterior portion of tumor
1K: Tumor for GOG study
1L: Section of right ovary and tube
1M: Left ovary and tube
1N: Right parametrial vessels
1P: Left parametrial vessels

2) Specimen 2 designated as "right pelvic lymph nodes" is received in formalin in a container labeled with the patient's name and medical record number and consists of fragments of fat and nodes, measuring approximately 3 x 2 x 1 cm in aggregate. The lymph nodes are dissected and submitted in cassette 2A -
-D.

3) Specimen 3 designated as "left pelvic lymph nodes" is received in formalin in a container labeled with the patient's name and medical record number and consists of a fat pad measuring approximately 5 x 3 x 1.5 cm. Sections are submitted in cassette 3A- E.

Microscopic Description:
A microscopic exam was performed.

Source: NCI Genomic Data Commons file abbfa71c-7120-4cea-a2dd-1d83d4cce5b2 (TCGA-AX-A3FS.1AEA9AC0-3B22-4819-9542-1F6A6AD474BC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).